CPTAC case C3N-01408 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46098b0b-a53e-425a-abc0-73561c447ea1

Demographics
Sex at birth: male; Race: asian; Year of birth: 1959; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 58.3 years (21,281 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 406 days (1.1 years); Progression or recurrence: no; Days to last follow up: 406 days (1.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm (a second GDC size field records 1 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 9; Margin status: Indeterminate.

Follow-up (1 entry)
- Days to follow up: 406 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 3.

Other clinical attributes
- Weight: 63 kg; Height: 170 cm; BMI: 21.8.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 4.7; Cigarettes per day: 3; Tobacco smoking onset year: 1986; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 36.

Biospecimens (9 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Samples C3N-01408-01, C3N-01408-04 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 250 mg.
- Sample C3N-01408-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 270 mg; Time between clamping and freezing: 22 minutes; Time between excision and freezing: 4 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01408-22: Section location: Lung; Percent tumor nuclei: 70; Percent necrosis: 15.
- Sample C3N-01408-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 260 mg.
- Sample C3N-01408-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 240 mg.
- Sample C3N-01408-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 250 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 8 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3N-01408-31, C3N-01408-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01408-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 7 days; Method of sample procurement: Blood Draw.
